CCDI case PBBVDB — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/0d758f6e-3415-4052-a3ed-30a81ac6ba33

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Desmoplastic infantile astrocytoma: ICD-O-3 morphology code: 9412/1; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 5.0 years (1,840 days).

Biospecimens (2 samples)
- Sample 0DII32: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DII42: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
